Surgical pathology report (de-identified scan), TCGA case TCGA-AL-3472, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AL-3472-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left renal mass.

Source of Specimen(s):

1: 2 Portions of 11th Rib

2: Mass Left Renal

3: Base of Mass

4: Base of Mass

Gross Description:

Received in four parts.

Source of tissue: 1. Labeled #1, "two portions 11th rib"

Gross description: Received fresh labeled ", two portions 11th rib" consists of two portions of pink-red bone with minimal attached soft tissue 1.2 x 1.1 x 0.3 cm and 2.5 x 1 x 0.4 cm. Entirely submitted in cassette 1A following fixation and decalcification.

Source of tissue: 2. Labeled #2, "left renal mass"

Frozen Section Diagnosis: 2FS RENAL CELL NEOPLASM FAVOR PAPILLARY TYPE.

MARGIN IS NEGATIVE PER [REDACTED]

Gross description: Received fresh for frozen section labeled ", left renal mass" consists of a 448 gram, 11 x 9 x

6.5 cm yellow-pink encapsulated mass. The specimen comes designated with a clip at the base. The base is inked black and the area of the clip is frozen for frozen section diagnosis. Further sectioning reveals yellow, possibly necrotic cut surfaces. A piece of the specimen is sent to Cytogenetics, and pictures are taken per surgeon. Representative sections are submitted as designated for microscopic evaluation.

Designation of sections: 2FS frozen section. 2A tumor in relation to normal. 2B-2E random sections all in relation to capsule. Please note that cassette 2E contains sections in relation to base.

Source of tissue: 3. Labeled #3, "base of mass"

Frozen Section Diagnosis: 3FS NO TUMOR SEEN [REDACTED]

Gross description: Received fresh for frozen section labeled , base of mass" consists of 0.5 x 0.4 x 0.2 cm

fragment of pink-tan soft tissue. Entirely frozen and submitted in cassette 3FS for microscopic evaluation.

Source of tissue: 4. Labeled #4, "lateral base of mass"

Frozen Section Diagnosis: 4FS NO TUMOR SEEN [REDACTED]

Gross description: Received fresh for frozen section labeled , lateral base of mass" consists of one irregular

[page 2 of 2]
fragment of tan soft tissue 0.5 x 0.3 x 0.2 cm. Entirely frozen and submitted in cassette 4FS for microscopic evaluation.

All specimens are placed in formalin at [REDACTED]

Final Diagnosis:

1. Two portions, 11th rib"

- No tumor seen.

2. Left renal mass:

- Renal cell carcinoma, papillary type (11.0 cm) type I.

- Angiolymphatic invasion is not identified.

- Resection margin free of tumor.

3. Base of mass:

- No tumor seen.

4. Lateral base of mass:

- No tumor seen.

pT2 No Mx

Procedures/Addenda

FC Cytogenetics Solid

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Papillary Renal Cell Carcinoma

KARYOTYPE: Abnormal karyotype: 47,X,-[REDACTED]+7,+17[20]

RESULTS: The renal mass was harvested after three and four days in culture. The chromosomes from twenty metaphases were counted and analyzed, and three of these metaphases were karyotyped by G-banding. The modal chromosome number was 47, and the cells were missing [REDACTED] chromosome and contained an extra copy of chromosomes 7 and 17. Loss of [REDACTED] and trisomy for chromosomes 7 and 17 have been reported in cases of papillary renal cell carcinoma and are consistent with this patient's diagnosis.

Source: NCI Genomic Data Commons file 5044ac9a-6f26-4219-b97c-64f8fde2ac5e (TCGA-AL-3472.ADB43717-1C90-4B8A-BB17-CB06C609A7E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).